Gene-level copy-number profile of tumor specimen ALCH-ABV1-TTP1-A from ALCHEMIST case ALCH-ABV1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.4 years (20,589 days).
Specimen ALCH-ABV1-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88e8c9c4-f4c5-4bc8-8531-02fd48e49107.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABV1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/a551bae7-a664-4ff2-95a8-ecf2aaa66660

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 293; copy number 2: 56,777; copy number 3: 951; copy number 4: 30; copy number 5: 231; copy number 6: 9; copy number 7: 24; copy number 8: 13; copy number 9: 23; copy number 10: 42.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:68,250,469–68,251,656, 1 gene (within-gene range 0–1): AL353608.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 342 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:55,954,105–61,232,937, 163 genes, copy number 5 (broad region; genes not listed).
- chr12:63,558,913–64,397,065, 21 genes, copy number 5 (within-gene range 1–5): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P.
- chr12:64,266,413–64,266,766, 1 gene, copy number 5 (within-gene range 2–5): OOEPP2.
- chr12:64,404,392–71,441,898, 149 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:73,648,666–74,171,830, 7 genes, copy number 5: AC087879.1, RNU6-1012P, LINC02445, U8, AC136188.1, LINC02394, AC090502.3.
- chr12:82,223,681–82,358,805, 1 gene, copy number 5 (within-gene range 3–5): CCDC59.

Autosomal genes at a single copy (total copy number 1): 293. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
